Somatic mutation profile of tumor specimen C3L-01687-03 (aliquot CPT0094630010_1) from CPTAC case C3L-01687, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 79.0 years (28,838 days).
Specimen C3L-01687-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bd75257-eadf-45b6-bf71-f7f6e00d307f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01687-31 (Blood Derived Normal), aliquot CPT0094670002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b29d9dd2-c7cb-4a22-ae8a-05df60354afa

The open-access MAF lists 47 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 6, Intron 5, Nonsense Mutation 2, Splice Region 2, Frame Shift Ins 2, 5'Flank 1, In Frame Del 1, 3'UTR 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>G p.H83D | Missense Mutation (SNP) | VAF 199/982 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 90/659 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADD2 | c.705G>A p.A235= | Splice Region (SNP) | VAF 18/120 reads (15%) | catalogued as rs781804198, COSV52472118; called by muse, mutect2
- ANKRD50 | c.997T>G p.L333V | Missense Mutation (SNP) | VAF 90/540 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV72385550; called by muse, mutect2, varscan2
- APBA1 | c.2468C>T p.A823V | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs1476460860; called by muse, mutect2
- DPYS | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 128/914 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs769403392; called by muse, mutect2, varscan2
- FCRL1 | c.104C>A p.T35N | Missense Mutation (SNP) | VAF 85/556 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs1407942494; called by muse, mutect2, varscan2
- FLNA | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 58/868 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs199766573; called by muse, mutect2
- HERC2 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 57/404 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs779830734, COSV55334806; called by muse, mutect2, varscan2
- KAT6B | c.5356G>A p.E1786K | Missense Mutation (SNP) | VAF 42/664 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs906740657, COSV54744157; called by muse, mutect2
- LAMA1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 91/838 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs200626690; called by muse, mutect2, varscan2
- PIK3CG | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 28/439 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs200175951, COSV63245400; called by muse, mutect2
- PKN2 | c.2533G>A p.V845M | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV65143304; called by muse, mutect2, varscan2
- PRKD2 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 50/290 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs763539356, COSV99354200; called by muse, mutect2
- RALB | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 119/779 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1388854390; called by muse, mutect2, varscan2
- RNMT | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 42/534 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1438601973, COSV100054832; called by muse, mutect2
- SLC35F3 | c.1091T>C p.I364T (on ENST00000366617 / NM_001300845.1; = p.I433T on NM_173508.4) | Missense Mutation (SNP) | VAF 70/956 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100784849; called by muse, mutect2
- SLC4A3 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs764732530; called by muse, mutect2
- THBS4 | c.783C>T p.C261= | Splice Region (SNP) | VAF 37/348 reads (11%) | catalogued as rs561944130; called by muse, mutect2, varscan2
- TRPM1 | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 91/691 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs377044822; called by muse, mutect2, varscan2
- UROC1 | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 143/849 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372570937; called by muse, mutect2, varscan2
- ANKFN1 | c.3187G>A p.D1063N (on ENST00000653862; = p.D916N on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/755 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- BRINP3 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 58/391 reads (15%) | called by muse, mutect2, varscan2
- DAAM2 | c.3115G>T p.D1039Y (on ENST00000274867 / NM_001201427.2; = p.D1038Y on NM_015345.3) | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DIDO1 | c.2609_2613del p.K870Tfs*8 | Frame Shift Del (DEL) | VAF 34/273 reads (12%) | called by mutect2, pindel, varscan2
- DIS3 | c.1518dup p.A507Cfs*2 | Frame Shift Ins (INS) | VAF 55/452 reads (12%) | called by mutect2, pindel, varscan2
- NBEA | c.3908T>A p.V1303D | Missense Mutation (SNP) | VAF 82/647 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- PKD1L3 | c.1522dup p.I508Nfs*2 | Frame Shift Ins (INS) | VAF 22/181 reads (12%) | called by mutect2, pindel, varscan2
- SLC25A14 | c.373T>C p.Y125H | Missense Mutation (SNP) | VAF 12/335 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLCO6A1 | c.1725C>A p.C575* | Nonsense Mutation (SNP) | VAF 17/306 reads (6%) | called by muse, mutect2
- TP53 | c.705_719del p.Y236_S240del | In Frame Del (DEL) | VAF 94/606 reads (16%) | called by mutect2, pindel
- VDR | c.1316G>A p.G439D | Missense Mutation (SNP) | VAF 32/391 reads (8%) | called by muse, mutect2
- WDR17 | c.952T>A p.L318I | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.242); called by muse, mutect2
- SAGE1 | c.1365C>T p.N455= | Silent (SNP) | VAF 36/272 reads (13%) | catalogued as rs782556186, COSV100186857; called by muse, mutect2, varscan2
- SDHC | c.276C>T p.L92= | Silent (SNP) | VAF 104/747 reads (14%) | catalogued as COSV100713603; called by muse, mutect2, varscan2
- SEC16A | c.1257G>A p.G419= | Silent (SNP) | VAF 87/546 reads (16%) | called by muse, mutect2, varscan2
- SHANK1 | c.4740A>G p.P1580= | Silent (SNP) | VAF 88/417 reads (21%) | catalogued as rs763099836; called by muse, mutect2, varscan2
- STK39 | c.1116T>C p.G372= | Silent (SNP) | VAF 26/456 reads (6%) | called by muse, mutect2
- ZNF217 | c.1659A>G p.Q553= | Silent (SNP) | VAF 128/838 reads (15%) | catalogued as rs752565233; called by muse, mutect2
- CCDC74B | c.296-157C>T | Intron (SNP) | VAF 28/484 reads (6%) | catalogued as rs781529448; called by muse, mutect2
- CSMD3 | c.7885+60G>T | Intron (SNP) | VAF 13/378 reads (3%) | called by muse, mutect2
- DENND3 | c.956+2228G>A | Intron (SNP) | VAF 58/328 reads (18%) | called by muse, mutect2, varscan2
- OBSCN | c.5138-1767C>A | Intron (SNP) | VAF 79/702 reads (11%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159592 C>T | 5'Flank (SNP) | VAF 28/209 reads (13%) | catalogued as rs752328712; called by muse, mutect2, varscan2
- SEH1L | c.*32T>C | 3'UTR (SNP) | VAF 124/389 reads (32%) | called by muse, mutect2, varscan2
- TGIF1 | c.-44-29A>G | Intron (SNP) | VAF 170/668 reads (25%) | called by muse, mutect2, varscan2
- UBL4A | c.-9G>A | 5'UTR (SNP) | VAF 34/177 reads (19%) | called by muse, mutect2, varscan2
